TCGA case TCGA-DV-5573 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: NCI Urologic Oncology Branch. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c6454371-1f84-4e8e-8c3a-2eac8380819e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 41 years; Vital status: Alive.

Diagnoses (4)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 41.8 years (15,264 days); Year of diagnosis: 2008; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes.
2. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Right; Classification of tumor: Prior primary; AJCC staging edition: 5th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Recombinant Interleukin-2; Days to treatment start: -2,436 days (-6.7 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
3. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Synchronous primary; AJCC staging edition: 7th; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Neuroendocrine carcinoma, NOS: ICD-O-3 morphology code: 8246/3; Tissue or organ of origin: Pancreas, NOS; Classification of tumor: Prior primary; AJCC staging edition: 5th.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,130 days (3.1 years); Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- Lactate Dehydrogenase: Normal.
- Hemoglobin: Low.
- Calcium: Normal.
- Platelets: Elevated.
- Leukocytes: Elevated.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DV-5573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-DV-5573-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-DV-5573-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-DV-5573-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DV-5573-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Pancreas; Other malignancy histological type: Neuroendocrine Tumor.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -2709.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -2738.
- Other malignancy form 2, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form 2, Drug treatment, Administered drug: Pharmaceutical therapy drug name: IL-2.
- Other malignancy form 3: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Kidney Clear Cell Renal Carcinoma.
- Other malignancy form 3, Surgery: Days from index date to other malignancy surgery: 749.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy pancreas cancer. No systemic chemotherapy or radition. Prior malignancy R KIRC treated with IL-2. Patient with synchronous L KIRC.
- Prior malignancy: Prior malignancy pancreas cancer. No systemic chemotherapy or radition. Prior malignancy R KIRC treated with IL-2. Patient with synchronous L KIRC.
- Synchronous malignancy: Prior malignancy pancreas cancer. No systemic chemotherapy or radition. Prior malignancy R KIRC treated with IL-2. Patient with synchronous L KIRC.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,130 days; disease-specific survival: no event (censored), 1,130 days; progression-free interval: no event (censored), 1,130 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-DV-5573-01): tumor purity 0.55, ploidy 2, whole-genome doublings 0 (call status: legacy_call).
